HCMI case HCM-BROD-0231-C25 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Pancreas. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1ae8657f-477f-4e1a-aef2-dd1c1ab5f26a

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1949; Vital status: Dead; Days to death: 227 days; Cause of death: Cancer Related.

Diagnoses (3)
1. Mucinous adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8480/3; ICD-10 code: C25.9; Tissue or organ of origin: Pancreas, NOS; Classification of tumor: primary; Age at diagnosis: 68.9 years (25,156 days); AJCC staging edition: 7th; AJCC clinical stage: Stage IV; AJCC pathologic T: TX; AJCC pathologic N: N0; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Metastasis at diagnosis: Metastasis, NOS; Prior treatment: No; Sites of involvement: Liver.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil + Irinotecan Hydrochloride + Leucovorin Calcium + Oxaliplatin; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Regimen or line of therapy: FOLFIRINOX; Days to treatment start: 12 days; Days to treatment end: 54 days.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Trametinib; Treatment intent type: Adjuvant; Initial disease status: Residual Disease; Days to treatment start: 137 days; Days to treatment end: 180 days.
   Recorded as not given: neoadjuvant treatment (type not reported); adjuvant Radiation Therapy, NOS, for residual disease; Surgery, NOS, for initial diagnosis; adjuvant Targeted Molecular Therapy, for residual disease.
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.7; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 68.9 years (25,156 days).
3. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C78.2; Tissue or organ of origin: Pancreas, NOS; Site of resection or biopsy: Liver; Classification of tumor: metastasis; Age at diagnosis: 69.1 years (25,246 days); Days to diagnosis: 90 days.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence anatomic site: Liver; Days to progression: 0 days.
- Days to follow up: 216 days; Disease response: Stable Disease; Progression or recurrence: No.
- Follow-up contact recording only the day: day 166.

Molecular and laboratory tests
- CEA: 1.9 ng/mL; Blood test normal range upper: 3.8.
- SMAD4 (IHC): Positive.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 72 kg; Height: 154 cm; BMI: 30.4.

Exposures
- Tobacco smoking status: Current Reformed Smoker, Duration Not Specified.

Family history
- Relative with cancer history: yes; Relationship type: First Degree Relative, NOS; Relationship primary diagnosis: Pancreas Cancer.

Biospecimens (6 samples)
- Sample HCM-BROD-0231-C25-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen. An open-access masked somatic mutation file (MAF) exists for this specimen and lists no variants.
- Sample HCM-BROD-0231-C25-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
- Samples HCM-BROD-0231-C25-85M, HCM-BROD-0231-C25-85N (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
- Samples HCM-BROD-0231-C25-86M, HCM-BROD-0231-C25-86N (2 with the same recorded description): Sample type: Expanded Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
